Gene-level copy-number profile of tumor specimen C3L-03272-02 from CPTAC case C3L-03272, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 67.8 years (24,779 days).
Specimen C3L-03272-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7e95e0ef-27dd-4336-8e59-c2249dd7af97.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-03272-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,739 have no estimate.
https://portal.gdc.cancer.gov/files/9fd636ac-0891-4e00-8701-f4b8222a5ff5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 4,013; copy number 2: 50,950; copy number 3: 3,444; copy number 4: 156; copy number 5: 209; copy number 6: 107; copy number 7: 2.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:170,639,606–170,651,338, 2 genes: OR4F7P, WBP1LP8.
- chr12:91,050,491–91,058,024, 1 gene: KERA.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 318 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:164,978,898–165,846,519, 6 genes, copy number 5: SI, Y_RNA, LINC02023, SLITRK3, LINC01322, BCHE.
- chr3:166,293,756–166,862,110, 9 genes, copy number 5: AC104629.1, LINC01326, AC072046.2, RN7SKP298, PSAT1P4, AC072046.1, CBX1P5, AC069439.2, AC069439.1.
- chr3:167,683,298–167,825,569, 4 genes, copy number 5: PDCD10, HMGN1P8, SERPINI1, AC079822.1.
- chr3:168,858,659–168,859,130, 1 gene, copy number 5: RPL21P43.
- chr3:169,709,295–174,286,644, 80 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr3:173,910,498–175,941,037, 18 genes, copy number 5–6 (within-gene range 5–7): NLGN1-AS1, RN7SKP234, ANAPC15P2, AC069218.1, NAALADL2, RN7SKP40, EEF1B2P8, NAALADL2-AS3, NAALADL2-AS2, MIR4789, RNU6-1233P, AC008180.3, RNU4-91P, AC119744.1, UBE2V1P2, RNU6-1317P, NAALADL2-AS1, AC104640.1.
- chr3:176,068,042–177,899,224, 21 genes, copy number 5–6: EI24P1, AC104640.2, AC117434.1, LINC01208, RNA5SP147, LINC01209, MTND5P15, TBL1XR1, TBL1XR1-AS1, Y_RNA, RNU6-681P, LINC00501, ASS1P7, AC117465.1, LINC00578, RN7SKP52, AC026355.3, AC026355.1, AC026355.2, AC026355.4, LINC02015.
- chr3:178,960,121–179,789,401, 23 genes, copy number 5–6: ZMAT3, Y_RNA, AC076966.2, PIK3CA, AC076966.1, KCNMB3, LRRFIP1P1, ZNF639, AC007823.1, MFN1, GNB4, AC007620.2, AC007620.3, AC007620.1, MTHFD2P7, ACTL6A, AC090425.3, AC090425.2, MRPL47, NDUFB5, AC090425.1, H3P13, USP13.
- chr3:180,161,886–180,325,059, 4 genes, copy number 5: RNA5SP149, AC134503.1, GAPDHP36, RALBP1P1.
- chr3:180,542,701–185,938,103, 131 genes, copy number 5–6 (broad region; genes not listed).
- chr7:73,005,541–73,111,140, 14 genes, copy number 5 (within-gene range 2–5): PMS2P7, Y_RNA, SPDYE8, PMS2P8, Y_RNA, AC211476.5, AC211476.3, SPDYE11, AC211476.4, Y_RNA, SPDYE9, PMS2P6, Y_RNA, SPDYE10P.
- chr14:18,333,726–18,412,264, 3 genes, copy number 5: CR383658.1, RNU6-458P, CR383658.2.
- chr21:13,038,160–13,120,807, 4 genes, copy number 5–7: ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Autosomal genes at a single copy (total copy number 1): 1,157. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
